Gene-level copy-number profile of tumor specimen C3N-02695-01 (profiled together with C3N-02695-02) from CPTAC case C3N-02695, project CPTAC-3 (Floor of mouth — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Floor of mouth, NOS; AJCC pathologic stage: Stage III; Tumor grade: G1; Age at diagnosis: 45.6 years (16,652 days).
Specimen C3N-02695-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Floor Of Mouth; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 8f6574bf-3909-42cb-ad7c-f34828ff2c8a.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-02695-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,708 have no estimate.
https://portal.gdc.cancer.gov/files/e2b763c6-cd71-4169-930f-0d32fd20fc89

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 54; copy number 1: 6,631; copy number 2: 46,132; copy number 3: 5,824; copy number 4: 13; copy number 5: 162; copy number 6: 69; copy number 8: 1; copy number 9: 5; copy number 10: 13; copy number 15: 11.

Homozygous deletions (total copy number 0; autosomes only): 53 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:9,799,423–9,803,784, 1 gene (within-gene range 0–2): AL513422.1.
- chr9:39,816,542–40,106,661, 5 genes (within-gene range 0–2): FGF7P3, BX664615.2, RN7SL763P, SNORA70, CR769767.1.
- chr9:39,983,821–39,984,401, 1 gene: RPL7AP49.
- chr15:21,293,653–21,295,201, 1 gene: AC068446.1.
- chr15:21,328,380–21,951,323, 36 genes: AC060814.4, AC060814.3, LONRF2P4, AC060814.2, CXADRP2, AC060814.1, GRAMD4P6, POTEB3, MIR3118-3, U6, NF1P9, MIR5701-2, AC183088.4, AC183088.2, AC183088.1, LINC02203, AC183088.3, AC135068.6, AC135068.2, AC135068.12, AC135068.11, AC135068.1, AC135068.4, AC135068.5, AC135068.8, AC135068.7, AC135068.9, AC135068.10, AC135068.3, AC134981.1, MIR3118-4, POTEB, RNU6-631P, ZNF519P3, NF1P2, MIR5701-3.
- chr15:21,990,074–22,126,434, 9 genes (within-gene range 0–8): AC134980.1, OR11H3P, AC134980.2, OR11K1P, OR4Q1P, OR4H6P, OR4M2, OR4N4, OR4N3P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 261 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:85,992,183–86,817,036, 8 genes, copy number 6–10 (within-gene range 2–10): CADM2-AS1, THAP12P2, AC107024.1, RNU6-1129P, AC108733.1, RN7SKP284, LINC02070, AC108706.1.
- chr11:39,873,782–46,739,506, 114 genes, copy number 5–10 (broad region; genes not listed).
- chr11:70,056,230–73,369,388, 121 genes, copy number 5 (broad region; genes not listed).
- chr15:21,980,277–21,981,245, 1 gene, copy number 8: OR11J6P.
- chr17:39,461,486–39,864,312, 17 genes, copy number 10–15: CDK12, RNU6-233P, AC009283.1, NEUROD2, AC087491.1, PPP1R1B, STARD3, TCAP, PNMT, PGAP3, ERBB2, MIR4728, MIEN1, GRB7, IKZF3, KRT8P34, AC090844.1.

Autosomal genes at a single copy (total copy number 1): 3,786. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
